Somatic mutation profile of tumor specimen 0DN51N from CCDI case PBCASF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,614 days).
Specimen 0DN51N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9df12a00-1d6d-4383-a503-49fc473c500b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN51E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14cc05f7-52e1-426c-954d-f3d9638a7beb

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDLBP | c.664C>A p.R222S | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as COSV100191654; called by muse, mutect2
- MAST4 | c.3422C>T p.P1141L (on ENST00000403625 / NM_001164664.2; = p.P952L on NM_015183.3) | Missense Mutation (SNP) | VAF 50/699 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754657959, COSV99845226; called by muse, mutect2
